Surgical pathology report (de-identified scan), TCGA case TCGA-KD-A5QS, project TCGA-SARC (Sarcoma), tissue source site Mount Sinai School of Medicine, specimen TCGA-KD-A5QS-01A (Primary Tumor).

ICD-0-3

Leiomyosarcoma NOS
8890/3
Site Uterus, myometrium
C54.2
JW 4/2/13

Leiomyosarcoma

CATEGORY: SARCOMA—LEIOMYOSARCOMA

FROM PRIMARY GYNECOLOGIC SURGERY

CLINICAL HISTORY - LMP with rapidly enlarging uterine / pelvic mass, with postmenopausal bleeding.

UTERUS, CERVIX, LEFT TUBE AND OVARY (527g) - Uterine high-grade leiomyosarcoma (11cm diameter), confined to the myometrium, with myometrial blood vascular space invasion. Otherwise, weakly proliferative endometrium, parakeratotic cervix, and benign ovary and fallopian tube. Histologic note: The tumor shows severe nuclear atypia, extensive necrosis, and mitotic amount of 61 figures per 10 high-power fields.

RIGHT TUBE AND OVARY - Ovarian serous cystadenoma. Mild chronic salpingitis.

RIGHT AORTIC LYMPH NODE - One small benign lymph node. Additional freely floating fragments of skeletal muscle, adipose tissue, blood clot and tumor.

LEFT PELVIC LYMPH NODE - Two benign lymph nodes.

LEFT PELVIC LYMPH NODE - Two benign lymph nodes.

FIGO Stage apparent IB.

IHPAA Discrepancy		/

Source: NCI Genomic Data Commons file 45aefddb-bfcd-427b-809b-a3923a162b98 (TCGA-KD-A5QS.754C4B00-19EB-43E7-A73A-D5A8A9C53FDC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).